Somatic mutation profile of tumor specimen C3N-01848-01 (aliquot CPT0099050009) from CPTAC case C3N-01848, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.3 years (24,957 days).
Specimen C3N-01848-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d12a1b1f-0f18-4a5f-a3dd-ade0926a6453.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01848-31 (Blood Derived Normal), aliquot CPT0099090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69762908-f805-464b-8cbc-05a83be0e4f4

The open-access MAF lists 369 somatic variants for this specimen: 259 protein-altering or splice-affecting, 72 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 72, Frame Shift Del 41, Intron 20, Frame Shift Ins 14, Nonsense Mutation 10, 3'UTR 7, RNA 5, In Frame Del 4, 5'UTR 3, Splice Site 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs968244943, COSV50461455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 44/200 reads (22%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- SMARCB1 | c.932C>T p.T311I (on ENST00000263121; = p.T357I on NM_003073.5) | Missense Mutation (SNP) | VAF 30/540 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555881567; ClinVar: likely pathogenic; called by muse, mutect2
- ADARB1 | c.2141G>A p.R714H (on ENST00000360697 / NM_001346687.2; = p.R674H on NM_001112.4) | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs773802034, COSV62346782; called by muse, mutect2, varscan2
- AKAP9 | c.4087G>A p.A1363T | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62344352; called by muse, mutect2, varscan2
- ALDH3B2 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs565722840, COSV62428716; called by muse, mutect2, varscan2
- ANAPC2 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867806917, COSV60570060; called by muse, mutect2, varscan2
- ANKRD52 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV99921092; called by muse, mutect2
- ANKRD61 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99551623; called by muse, mutect2, varscan2
- ANO4 | c.2512C>T p.R838* (on ENST00000392977 / NM_001286615.2; = p.R803* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 13/363 reads (4%) | catalogued as rs1334303212, COSV54595105; called by muse, mutect2
- AP1M2 | c.969del p.R324Dfs*18 | Frame Shift Del (DEL) | VAF 63/300 reads (21%) | catalogued as COSV51565954; called by mutect2, pindel, varscan2
- ARHGAP23 | c.2933G>A p.S978N | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423572349; called by muse, mutect2, varscan2
- ARHGAP39 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs973591401, COSV52774381; called by muse, mutect2, varscan2
- ARHGAP5 | c.2965C>A p.P989T | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.904); catalogued as COSV100565049; called by muse, mutect2, varscan2
- ATF7IP | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as rs1464541439; called by muse, mutect2, varscan2
- ATP13A2 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 15/135 reads (11%) | catalogued as rs1264582344; called by muse, mutect2, varscan2
- ATP13A2 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 47/387 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs764125787; called by muse, mutect2, varscan2
- BRD4 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 50/271 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.094); catalogued as rs1330924461; called by muse, mutect2, varscan2
- BRDT | c.1007A>C p.K336T | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs1064567; called by muse, mutect2, varscan2
- C6orf136 | c.149_151del p.P50del | In Frame Del (DEL) | VAF 8/79 reads (10%) | catalogued as rs745619360; called by pindel, varscan2
- C9orf50 | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV65252636; called by muse, mutect2, varscan2
- CACNA1A | c.7288G>A p.G2430R | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV64192889; called by muse, mutect2, varscan2
- CCAR1 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.018); catalogued as rs1354811354; called by muse, mutect2, varscan2
- CDC45 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 23/301 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs750355811; called by muse, mutect2
- CEBPE | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52828869; called by muse, mutect2
- CIC | c.3743del p.P1248Hfs*54 | Frame Shift Del (DEL) | VAF 26/111 reads (23%) | catalogued as COSV50671496; called by mutect2, pindel, varscan2
- CLCN4 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV101073632; called by muse, mutect2, varscan2
- CNTNAP1 | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1029584700, COSV99226513; called by muse, mutect2
- COL11A2 | c.4027G>A p.A1343T (on ENST00000341947 / NM_080680.3; = p.A1236T on NM_080679.2) | Missense Mutation (SNP) | VAF 66/364 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.045); catalogued as rs759017753, COSV59497650; called by muse, mutect2, varscan2
- CYSLTR1 | c.657dup p.S220Ifs*10 | Frame Shift Ins (INS) | VAF 22/132 reads (17%) | catalogued as rs35745545; called by mutect2, varscan2
- DLG1 | c.2129_2131del p.E710del (on ENST00000419354 / NM_001290983.1; = p.E732del on NM_004087.2) | In Frame Del (DEL) | VAF 17/111 reads (15%) | catalogued as rs1271622068; called by pindel, varscan2
- DMXL2 | c.3390G>T p.K1130N | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as rs974960091; called by mutect2, varscan2
- DNAAF5 | c.1684C>A p.H562N | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV99859266; called by muse, mutect2, varscan2
- DOCK10 | c.521del p.G174Vfs*24 | Frame Shift Del (DEL) | VAF 23/176 reads (13%) | catalogued as rs746265647, COSV99288335; called by mutect2, pindel, varscan2
- DSTYK | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1301056685; called by muse, mutect2, varscan2
- DUOX2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as rs1301377653; called by muse, mutect2, varscan2
- ECD | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769632241; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.371); catalogued as COSV57517053; called by muse, mutect2, varscan2
- ENHO | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs753911189; called by muse, mutect2, varscan2
- EPG5 | c.3358G>A p.V1120M | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs758682538; called by muse, mutect2, varscan2
- EPHA8 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs771365576, COSV51268187; called by muse, mutect2, varscan2
- EPS8L2 | c.2047A>G p.M683V | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs879145256; called by muse, mutect2, varscan2
- FAM83H | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs1184155884, COSV101186985; called by muse, mutect2
- FBXO41 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs779443682, COSV54587394; called by muse, mutect2, varscan2
- FIGNL2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs1353895560; called by muse, mutect2, varscan2
- FLNC | c.6952C>T p.R2318W | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs779924235, COSV57959022; called by muse, mutect2
- FREM3 | c.4211C>T p.T1404I | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61682285; called by muse, mutect2
- H1-2 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 22/327 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs967486148, COSV59190460; called by muse, mutect2
- HCRTR2 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 73/406 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV63798993; called by muse, mutect2, varscan2
- HEATR1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as rs760724482; called by muse, mutect2, varscan2
- HMX1 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs865936244; called by muse, mutect2
- HNRNPA2B1 | c.7-3dup | Splice Region (INS) | VAF 15/98 reads (15%) | catalogued as rs759915055; called by mutect2, pindel
- HPSE2 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.459); catalogued as rs750825727; called by muse, mutect2, varscan2
- HSP90AA1 | c.35T>C p.M12T | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.061); catalogued as rs747700636; called by muse, mutect2
- IFT140 | c.3848C>T p.A1283V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63698152; called by muse, mutect2
- INPP4A | c.2702G>A p.R901H (on ENST00000074304 / NM_001134224.1; = p.R862H on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471383993, COSV50785371, COSV99302867; called by muse, mutect2
- INPPL1 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773899602; called by muse, mutect2, varscan2
- IPO4 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs748753318; called by muse, mutect2, varscan2
- ITGAD | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs1240326488, COSV66760147; called by muse, mutect2, varscan2
- ITGB1BP2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as rs986179604; called by muse, mutect2, varscan2
- KATNIP | c.3086G>A p.R1029H | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs369563369; called by muse, mutect2, varscan2
- KCTD12 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.153); catalogued as rs1566375386; called by muse, mutect2, varscan2
- KIAA0319 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.376); catalogued as rs376451243; called by muse, mutect2, varscan2
- KIAA1549 | c.5276del p.P1759Rfs*66 | Frame Shift Del (DEL) | VAF 26/140 reads (19%) | catalogued as COSV54318123; called by mutect2, pindel, varscan2
- KLHL15 | c.1330T>A p.C444S | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.221); catalogued as COSV100044488; called by muse, mutect2, varscan2
- KMT2D | c.11860C>T p.Q3954* | Nonsense Mutation (SNP) | VAF 42/363 reads (12%) | catalogued as CD146904; called by muse, mutect2, varscan2
- KRT18 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs746898922, COSV101184077; called by muse, mutect2, varscan2
- KRT6B | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 104/524 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs190319305, COSV52886409; called by muse, mutect2, varscan2
- KRT9 | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 22/294 reads (7%) | PolyPhen benign (0.005); catalogued as rs776803750; called by muse, mutect2
- LANCL2 | c.505T>C p.C169R | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV54648356; called by muse, mutect2, varscan2
- LRP3 | c.1952del p.P651Qfs*58 | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | catalogued as rs1480032725; called by mutect2, pindel, varscan2
- LTBP3 | c.2501C>T p.A834V | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV54216487; called by muse, mutect2
- LUM | c.893T>C p.L298P | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs777101297; called by muse, mutect2, varscan2
- MBD5 | c.3260C>T p.A1087V | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1479424507, COSV68696905; ClinVar: likely benign; called by muse, mutect2
- MTG1 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs148997160; called by muse, mutect2, varscan2
- MYO15A | c.3610-8T>A | Splice Region (SNP) | VAF 78/346 reads (23%) | catalogued as rs765041022, COSV52751650; called by muse, mutect2, varscan2
- NGLY1 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs1559535370; called by muse, mutect2
- NKX3-2 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); catalogued as COSV66711473; called by muse, mutect2, varscan2
- NPHS1 | c.2725G>A p.V909M | Missense Mutation (SNP) | VAF 66/358 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757413070; called by muse, mutect2, varscan2
- NRXN1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs200202367, COSV68008273; called by muse, mutect2, varscan2
- NT5DC3 | c.1534G>A p.V512I | Missense Mutation (SNP) | VAF 63/311 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs750569608, COSV67322568; called by muse, mutect2, varscan2
- OSBPL7 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs148584339; called by muse, mutect2, varscan2
- PA2G4 | c.1117_1119del p.K373del | In Frame Del (DEL) | VAF 30/176 reads (17%) | catalogued as rs1174297940; called by pindel, varscan2
- PALM | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370222652; called by muse, mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | catalogued as rs747416036; called by mutect2, varscan2
- PIM2 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV50234128; called by muse, mutect2
- PLEC | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs782753302; called by muse, mutect2, varscan2
- PLXNA2 | c.5627G>A p.R1876Q | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs778714938, COSV65439252; called by muse, mutect2, varscan2
- PNPLA7 | c.2443G>A p.V815M | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as rs191119649; called by muse, mutect2, varscan2
- POLD2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs568159170, COSV56255416; called by muse, mutect2, varscan2
- PRPF4B | c.611del p.G204Vfs*77 | Frame Shift Del (DEL) | VAF 50/202 reads (25%) | catalogued as COSV61783599; called by mutect2, pindel, varscan2
- PTEN | c.750_751del p.C250Wfs*2 | Frame Shift Del (DEL) | VAF 128/385 reads (33%) | catalogued as rs780264945; called by pindel, varscan2
- RASSF1 | c.679C>T p.R227C (on ENST00000357043 / NM_170714.2; = p.R223C on NM_007182.5) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs898332991, COSV51701763; called by muse, mutect2, varscan2
- REEP5 | c.424C>A p.R142S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99810012; called by muse, mutect2, varscan2
- REG1A | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 83/410 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1401496725, COSV52068880, COSV52071650; called by muse, mutect2, varscan2
- RYR2 | c.4762G>A p.V1588M | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV100768849; called by muse, mutect2, varscan2
- RYR3 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); catalogued as rs757325144, COSV66782669; called by muse, mutect2, varscan2
- RYR3 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.517); catalogued as rs752181610, COSV66808576; called by muse, varscan2
- SBF1 | c.4769C>T p.T1590M | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs371896005; called by muse, mutect2, varscan2
- SLC22A18AS | c.666dup p.N223Qfs*8 | Frame Shift Ins (INS) | VAF 14/82 reads (17%) | catalogued as rs763131197; called by mutect2, varscan2
- SLC24A1 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752066024, COSV99978185; called by muse, mutect2, varscan2
- SLC6A7 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 47/278 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773688110, COSV57938475; called by muse, mutect2, varscan2
- SLC8A3 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100776308; called by muse, mutect2, varscan2
- SMPD1 | c.1001T>C p.I334T | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs759950370; called by muse, mutect2, varscan2
- SP9 | c.597del p.L200Sfs*83 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as COSV67602621; called by mutect2, pindel
- SPINK5 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 27/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs550961797; called by muse, mutect2
- SPNS1 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1285520350; called by muse, mutect2, varscan2
- TAFA2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); catalogued as rs1380109498, COSV69171343, COSV69176822; called by muse, mutect2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 29/160 reads (18%) | catalogued as rs745872748; called by mutect2, varscan2
- TCTN2 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs376996387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEKT3 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs753700946, COSV58627703, COSV58629495; called by muse, mutect2
- TLR5 | c.2159G>A p.S720N | Missense Mutation (SNP) | VAF 25/414 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV60560168; called by muse, mutect2
- TNFSF10 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757021342, COSV99577947; called by muse, mutect2, varscan2
- TNRC18 | c.4079C>T p.P1360L | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs748041580; called by muse, mutect2, varscan2
- TRIO | c.3043G>A p.A1015T | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.874); catalogued as rs745774257, COSV100710895; called by muse, mutect2, varscan2
- TRPV5 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs141909216, COSV54685597; called by muse, mutect2
- TTC3 | c.5519C>T p.P1840L | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs1195484469; called by muse, mutect2, varscan2
- VOPP1 | c.263del p.P88Rfs*3 | Frame Shift Del (DEL) | VAF 23/121 reads (19%) | catalogued as COSV53390629; called by mutect2, pindel, varscan2
- VPS52 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as rs1160686925; called by muse, mutect2
- WDR19 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs759803480; called by muse, mutect2
- WDR90 | c.3038del p.P1013Qfs*98 | Frame Shift Del (DEL) | VAF 24/142 reads (17%) | catalogued as rs752097396; called by mutect2, varscan2
- ZBTB6 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); catalogued as rs1279380292; called by muse, mutect2
- ZFHX4 | c.6162_6165del p.P2056Hfs*26 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | catalogued as rs1554575033; called by mutect2, varscan2
- ZNF443 | c.1777T>C p.C593R | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754113234; called by muse, mutect2, varscan2
- ZNF512B | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs149218980; called by muse, mutect2
- ZNF845 | c.1021T>C p.Y341H | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as rs773248866; called by muse, mutect2, varscan2
- ADAMTS2 | c.3418dup p.L1140Pfs*24 | Frame Shift Ins (INS) | VAF 25/173 reads (14%) | called by mutect2, pindel
- ADAMTSL1 | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALG3 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 15/371 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); called by muse, mutect2
- ANKRD31 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ANLN | c.1356del p.G453Afs*9 | Frame Shift Del (DEL) | VAF 37/178 reads (21%) | called by mutect2, pindel, varscan2
- APOB | c.9446A>G p.D3149G | Missense Mutation (SNP) | VAF 38/353 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ARMCX6 | c.352T>C p.C118R | Missense Mutation (SNP) | VAF 77/395 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ARRB2 | c.544del p.Q182Sfs*36 | Frame Shift Del (DEL) | VAF 37/302 reads (12%) | called by mutect2, pindel, varscan2
- ARRDC5 | c.429C>A p.H143Q (on ENST00000381781; = p.H129Q on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/344 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.062); called by muse, mutect2
- ATIC | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 90/436 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ATP2C2 | c.1189T>C p.S397P | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN2 | c.2038+1del p.X680_splice (on ENST00000550104; = p.X520_splice on NM_002973.4) | Splice Site (DEL) | VAF 62/267 reads (23%) | called by mutect2, pindel, varscan2
- BPIFB3 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BROX | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- C22orf31 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 68/400 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCHCR1 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- CDKN1C | c.35T>C p.M12T | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- CHM | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.184); called by muse, mutect2
- CHPF | c.1088G>A p.S363N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- CIC | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- COX11 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRADD | c.451A>T p.N151Y | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- CSNK2A1 | c.900C>A p.F300L | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.043); called by mutect2, varscan2
- CSNK2A3 | c.1056G>C p.M352I | Missense Mutation (SNP) | VAF 84/460 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTCF | c.769del p.I257Lfs*6 | Frame Shift Del (DEL) | VAF 32/138 reads (23%) | called by mutect2, pindel
- DDX49 | c.1061A>C p.Q354P | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- DGKZ | c.35del p.G12Efs*26 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- DHX34 | c.1292del p.P431Lfs*25 | Frame Shift Del (DEL) | VAF 56/253 reads (22%) | called by mutect2, pindel, varscan2
- DOP1A | c.7021C>T p.Q2341* | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- ERCC6 | c.4004G>A p.R1335K | Missense Mutation (SNP) | VAF 49/315 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ERI2 | c.52A>T p.I18F | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM205A | c.2897C>T p.A966V | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- FAM205A | c.1639A>G p.T547A | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM89A | c.227del p.A76Gfs*150 | Frame Shift Del (DEL) | VAF 19/160 reads (12%) | called by mutect2, pindel, varscan2
- FBN1 | c.2812C>T p.P938S | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCHSD2 | c.2204T>C p.V735A | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, varscan2
- FLAD1 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 63/408 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- FLG | c.7675A>C p.T2559P | Missense Mutation (SNP) | VAF 80/585 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FLNA | c.4254G>T p.E1418D | Missense Mutation (SNP) | VAF 39/397 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.098); called by muse, mutect2
- FOXA2 | c.1042dup p.H348Pfs*14 (on ENST00000377115 / NM_153675.3; = p.H354Pfs*14 on NM_021784.5) | Frame Shift Ins (INS) | VAF 15/115 reads (13%) | called by mutect2, pindel
- GK3P | c.1093del p.S365Rfs*15 | Frame Shift Del (DEL) | VAF 60/372 reads (16%) | called by mutect2, pindel, varscan2
- GOLGA6L9 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 54/558 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- GPR17 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GRSF1 | c.807_809del p.F270del | In Frame Del (DEL) | VAF 18/103 reads (17%) | called by pindel, varscan2
- HECTD1 | c.4534G>A p.A1512T | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HELB | c.2674T>C p.S892P | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IL10RB | c.347del p.P116Lfs*5 | Frame Shift Del (DEL) | VAF 76/410 reads (19%) | called by mutect2, pindel, varscan2
- INPP5F | c.1321del p.X441_splice | Splice Site (DEL) | VAF 35/96 reads (36%) | called by mutect2, pindel, varscan2
- IPO7 | c.1065del p.P356Hfs*2 | Frame Shift Del (DEL) | VAF 42/185 reads (23%) | called by mutect2, pindel, varscan2
- IRF5 | c.611del p.P204Lfs*36 | Frame Shift Del (DEL) | VAF 12/132 reads (9%) | called by mutect2, pindel
- KCNB1 | c.79A>G p.K27E | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- KCP | c.2664del p.S889Afs*136 (on ENST00000620378; = p.S949Afs*136 on NM_001366122.1) | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- KCTD13 | c.854dup p.A286Sfs*13 | Frame Shift Ins (INS) | VAF 16/170 reads (9%) | called by mutect2, pindel
- KDM5C | c.577dup p.H193Pfs*27 | Frame Shift Ins (INS) | VAF 40/459 reads (9%) | called by mutect2, pindel
- KDM5C | c.443del p.N148Ifs*86 | Frame Shift Del (DEL) | VAF 38/365 reads (10%) | called by mutect2, varscan2
- KIFC1 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2B | c.6666dup p.T2223Hfs*80 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | called by pindel, varscan2
- KMT2E | c.1657dup p.T553Nfs*4 | Frame Shift Ins (INS) | VAF 14/136 reads (10%) | called by mutect2, pindel
- KPNA3 | c.112A>G p.K38E | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KRTAP12-1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 64/298 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- LACTBL1 | c.566T>C p.V189A (on ENST00000618559; = p.V234A on NM_001289974.2) | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.581); called by muse, mutect2
- LBR | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- LGMN | c.1266del p.K422Nfs*89 | Frame Shift Del (DEL) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- MALRD1 | c.6076C>T p.P2026S | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MCM3AP | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 24/425 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- MED12 | c.92A>G p.Q31R | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MGAM | c.4757C>T p.T1586I | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- MMP11 | c.736A>G p.S246G | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 21/93 reads (23%) | called by mutect2, pindel, varscan2
- NAA15 | c.907+1G>C p.X303_splice | Splice Site (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2, varscan2
- NAV2 | c.5135C>T p.T1712I (on ENST00000396087 / NM_001244963.2; = p.T1656I on NM_145117.5) | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2
- NBAS | c.2652T>G p.N884K | Missense Mutation (SNP) | VAF 74/332 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by mutect2, varscan2
- NBEAL2 | c.3737T>C p.V1246A | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- NCK2 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- NR2F1 | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 15/351 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- NRM | c.187dup p.L63Pfs*21 | Frame Shift Ins (INS) | VAF 16/130 reads (12%) | called by mutect2, pindel
- OLAH | c.380dup p.L127Ffs*19 (on ENST00000378228 / NM_001039702.3; = p.L180Ffs*19 on NM_018324.3) | Frame Shift Ins (INS) | VAF 16/156 reads (10%) | called by mutect2, pindel
- OR11H6 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); called by muse, mutect2
- OR13G1 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- OR51S1 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5M10 | c.195C>A p.H65Q | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PER2 | c.2672T>A p.V891D | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PLIN3 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); called by muse, mutect2
- PPP4R3C | c.1010del p.F337Sfs*23 | Frame Shift Del (DEL) | VAF 25/154 reads (16%) | called by mutect2, varscan2
- PPP4R3C | c.302A>G p.Q101R | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PRDM13 | c.1960C>A p.P654T | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRKAR2A | c.731del p.N244Ifs*22 | Frame Shift Del (DEL) | VAF 24/126 reads (19%) | called by mutect2, pindel, varscan2
- PROB1 | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.234); called by muse, mutect2
- RAD17 | c.263del p.N88Mfs*30 (on ENST00000380774 / NM_133339.2; = p.N77Mfs*30 on NM_002873.1) | Frame Shift Del (DEL) | VAF 22/144 reads (15%) | called by mutect2, pindel, varscan2
- RAPH1 | c.3258del p.I1087Lfs*30 | Frame Shift Del (DEL) | VAF 54/254 reads (21%) | called by mutect2, varscan2
- RBM6 | c.293del p.G98Efs*56 | Frame Shift Del (DEL) | VAF 66/253 reads (26%) | called by mutect2, pindel, varscan2
- SCAF4 | c.2603C>A p.P868H | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SEC16A | c.4456C>T p.Q1486* | Nonsense Mutation (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
- SETD1B | c.1802dup p.D602Gfs*11 | Frame Shift Ins (INS) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- SHC1 | c.1517G>T p.G506V (on ENST00000368445 / NM_183001.5; = p.G397V on NM_003029.5) | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC25A30 | c.830T>G p.I277S | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC26A8 | c.2115del p.R706Gfs*34 | Frame Shift Del (DEL) | VAF 43/263 reads (16%) | called by mutect2, pindel, varscan2
- SND1 | c.1451C>A p.A484D | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- SPATA31A3 | c.1929G>A p.W643* | Nonsense Mutation (SNP) | VAF 29/531 reads (5%) | called by muse, mutect2
- SPTBN5 | c.6985C>G p.P2329A | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SSX2IP | c.1167A>T p.E389D | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- STAT5A | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- STK25 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SULT1C4 | c.427A>G p.M143V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYP | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TBC1D8 | c.113dup p.G39Rfs*67 | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- TCEA2 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- TERF2 | c.1241A>G p.E414G | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- THRA | c.1354A>G p.I452V | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIMM17A | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 19/486 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2
- TMEM218 | c.128del p.L43Yfs*6 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, varscan2
- TNFRSF13C | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2
- TNFRSF18 | c.555dup p.G186Wfs*? | Frame Shift Ins (INS) | VAF 26/223 reads (12%) | called by mutect2, pindel, varscan2
- TNRC18 | c.1276C>A p.L426M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, varscan2
- TP53BP1 | c.926A>T p.Q309L | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, varscan2
- TRIR | c.354_355insG p.R119Afs*23 | Frame Shift Ins (INS) | VAF 27/93 reads (29%) | called by mutect2, pindel, varscan2
- TRPA1 | c.3180del p.K1060Nfs*8 | Frame Shift Del (DEL) | VAF 61/343 reads (18%) | called by mutect2, pindel, varscan2
- TRPM4 | c.294T>G p.D98E | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.28); called by muse, varscan2
- TRRAP | c.3331G>A p.G1111R | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TTC6 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 66/349 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- UFL1 | c.1832T>A p.I611N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- UNC80 | c.4659del p.D1554Ifs*5 | Frame Shift Del (DEL) | VAF 32/153 reads (21%) | called by mutect2, pindel, varscan2
- USP26 | c.1215G>A p.W405* | Nonsense Mutation (SNP) | VAF 76/309 reads (25%) | called by muse, mutect2, varscan2
- VPS35 | c.2228del p.L743* | Frame Shift Del (DEL) | VAF 43/333 reads (13%) | called by mutect2, pindel, varscan2
- VPS35 | c.2128T>C p.C710R | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WIPF3 | c.893del p.P298Lfs*76 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- XPO4 | c.2027A>G p.Q676R | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2
- YLPM1 | c.254del p.P85Lfs*7 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- ZNF441 | c.1630A>G p.S544G | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ZNF513 | c.423del p.L143Cfs*23 | Frame Shift Del (DEL) | VAF 33/167 reads (20%) | called by mutect2, pindel, varscan2
- ZNF805 | c.1688G>A p.G563E | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, varscan2
- ZNF83 | c.892T>C p.F298L | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ZSWIM6 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB1 | c.2515C>T p.L839= | Silent (SNP) | VAF 55/239 reads (23%) | called by muse, mutect2, varscan2
- APOBEC3C | c.273C>T p.Y91= | Silent (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- ARAF | c.516G>A p.S172= | Silent (SNP) | VAF 24/165 reads (15%) | catalogued as rs56202823, COSV51694528; called by muse, mutect2, varscan2
- ARR3 | c.306G>C p.L102= | Silent (SNP) | VAF 37/217 reads (17%) | catalogued as COSV57204269; called by muse, mutect2, varscan2
- ATG7 | c.366T>C p.L122= | Silent (SNP) | VAF 56/316 reads (18%) | called by muse, mutect2, varscan2
- ATP2B4 | c.231G>A p.R77= | Silent (SNP) | VAF 52/446 reads (12%) | called by muse, varscan2
- ATP6V0D1 | c.954C>T p.F318= | Silent (SNP) | VAF 17/333 reads (5%) | catalogued as rs764219820; called by muse, mutect2
- ATP6V0D2 | c.732C>T p.F244= | Silent (SNP) | VAF 30/175 reads (17%) | catalogued as rs768968754, COSV53418701; called by muse, mutect2, varscan2
- BIN2 | c.273C>T p.S91= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as rs750169427, COSV57203572; called by muse, mutect2, varscan2
- BTBD2 | c.765G>A p.A255= | Silent (SNP) | VAF 21/196 reads (11%) | catalogued as rs759408613, COSV55307320; called by muse, mutect2, varscan2
- C10orf67 | c.147C>T p.C49= (on ENST00000323327; = p.C50= on NM_153714.3) | Silent (SNP) | VAF 95/368 reads (26%) | catalogued as rs1448401784; called by muse, mutect2, varscan2
- C16orf82 | c.379C>T p.L127= | Silent (SNP) | VAF 56/246 reads (23%) | called by muse, mutect2, varscan2
- C5orf63 | c.75C>A p.A25= | Silent (SNP) | VAF 43/219 reads (20%) | called by muse, mutect2, varscan2
- CACNA1A | c.159G>A p.A53= | Silent (SNP) | VAF 62/324 reads (19%) | catalogued as rs767892925, COSV64191122; called by muse, mutect2, varscan2
- CCDC168 | c.16201C>T p.L5401= | Silent (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- CCN1 | c.444T>C p.P148= | Silent (SNP) | VAF 61/378 reads (16%) | called by muse, mutect2, varscan2
- CEP131 | c.2511G>A p.R837= (on ENST00000269392 / NM_001319228.2; = p.R834= on NM_014984.4) | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as rs1464470645; called by muse, mutect2, varscan2
- CFTR | c.4173A>C p.A1391= | Silent (SNP) | VAF 45/204 reads (22%) | called by muse, mutect2, varscan2
- CLUH | c.372G>T p.T124= (on ENST00000435359; = p.T162= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/209 reads (9%) | called by muse, mutect2, varscan2
- CNTF | c.573C>T p.S191= | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as rs1222627017, COSV60160282; called by muse, mutect2, varscan2
- CPSF1 | c.3339C>T p.T1113= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as rs147864352; called by muse, mutect2, varscan2
- DCN | c.171C>T p.R57= | Silent (SNP) | VAF 28/285 reads (10%) | called by muse, mutect2, varscan2
- ECT2L | c.1677C>A p.L559= | Silent (SNP) | VAF 31/168 reads (18%) | called by muse, mutect2, varscan2
- ERVV-2 | c.111G>A p.S37= | Silent (SNP) | VAF 37/205 reads (18%) | catalogued as rs1464875195; called by muse, mutect2, varscan2
- FAM20A | c.1233G>A p.R411= | Silent (SNP) | VAF 40/451 reads (9%) | catalogued as rs749771026; called by muse, mutect2
- FAM20A | c.186G>A p.S62= | Silent (SNP) | VAF 30/254 reads (12%) | called by muse, varscan2
- FAM91A1 | c.1596C>T p.V532= | Silent (SNP) | VAF 45/201 reads (22%) | catalogued as rs1233040783; called by muse, mutect2, varscan2
- GATA6 | c.201G>A p.T67= | Silent (SNP) | VAF 25/131 reads (19%) | called by muse, mutect2, varscan2
- GIT2 | c.1305C>T p.N435= | Silent (SNP) | VAF 41/241 reads (17%) | catalogued as rs759642073; called by muse, mutect2, varscan2
- GPT2 | c.528G>A p.A176= | Silent (SNP) | VAF 18/205 reads (9%) | catalogued as rs145871423, COSV100412960, COSV100413089; called by muse, mutect2
- GRIN1 | c.1956G>A p.A652= | Silent (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- IRAK1 | c.1602C>G p.A534= | Silent (SNP) | VAF 34/147 reads (23%) | catalogued as COSV64110559; called by muse, mutect2, varscan2
- ITGA10 | c.1713G>A p.A571= | Silent (SNP) | VAF 18/436 reads (4%) | catalogued as rs782328114, COSV65197625; called by muse, mutect2
- KATNIP | c.3501C>T p.G1167= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs769197995, COSV55189709; called by muse, mutect2
- KRTAP12-4 | c.165C>T p.C55= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as rs1555942125; called by muse, mutect2, varscan2
- LAMC2 | c.2445G>A p.G815= | Silent (SNP) | VAF 17/480 reads (4%) | catalogued as rs1045015856; called by muse, mutect2
- MTA1 | c.2047C>A p.R683= | Silent (SNP) | VAF 28/398 reads (7%) | catalogued as COSV58759352; called by muse, mutect2
- MUC5B | c.12393G>A p.Q4131= | Silent (SNP) | VAF 65/364 reads (18%) | called by muse, mutect2, varscan2
- MYH8 | c.1452C>T p.T484= | Silent (SNP) | VAF 26/445 reads (6%) | called by muse, mutect2
- NOTCH4 | c.2577C>T p.C859= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV66682170; called by muse, mutect2, varscan2
- NR4A3 | c.648G>A p.T216= | Silent (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.427C>T p.L143= (on ENST00000259318 / NM_001136562.3; = p.L374= on NM_007203.5) | Silent (SNP) | VAF 21/180 reads (12%) | called by muse, mutect2, varscan2
- PANX2 | c.690G>A p.R230= | Silent (SNP) | VAF 11/130 reads (8%) | called by muse, mutect2
- PLEKHA5 | c.156G>A p.R52= | Silent (SNP) | VAF 9/135 reads (7%) | called by muse, mutect2
- PLOD3 | c.741G>A p.T247= | Silent (SNP) | VAF 51/189 reads (27%) | catalogued as rs1207090212; called by muse, mutect2, varscan2
- PSMG1 | c.351A>C p.T117= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- PTPRT | c.3927C>T p.D1309= | Silent (SNP) | VAF 23/283 reads (8%) | catalogued as rs375333902; called by muse, mutect2
- RGS9 | c.1170C>A p.A390= | Silent (SNP) | VAF 35/411 reads (9%) | called by muse, mutect2
- RPS6KC1 | c.1146C>T p.R382= | Silent (SNP) | VAF 22/448 reads (5%) | called by muse, mutect2
- RREB1 | c.1605G>T p.P535= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV58553124, COSV58561135; called by muse, mutect2, varscan2
- SARDH | c.2538C>T p.G846= | Silent (SNP) | VAF 26/406 reads (6%) | catalogued as COSV64101264; called by muse, mutect2
- SDC1 | c.681T>C p.P227= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- SFPQ | c.1914T>C p.G638= | Silent (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- SFTPA2 | c.480C>T p.G160= | Silent (SNP) | VAF 27/291 reads (9%) | called by muse, mutect2, varscan2
- SLC37A1 | c.396C>T p.F132= | Silent (SNP) | VAF 11/134 reads (8%) | catalogued as rs777659037; called by muse, mutect2
- SMURF2 | c.933C>T p.G311= | Silent (SNP) | VAF 24/188 reads (13%) | called by muse, mutect2, varscan2
- SMYD3 | c.886C>T p.L296= (on ENST00000490107 / NM_001375962.1; = p.L237= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/379 reads (4%) | called by muse, mutect2
- SSTR4 | c.96G>A p.A32= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs770885264, COSV99658344; called by muse, mutect2, varscan2
- SYDE1 | c.1893C>T p.P631= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- TAS2R60 | c.720G>A p.Q240= | Silent (SNP) | VAF 38/168 reads (23%) | called by muse, mutect2, varscan2
- THAP4 | c.963C>T p.S321= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs778142077; called by muse, mutect2, varscan2
- TMBIM1 | c.528C>T p.G176= | Silent (SNP) | VAF 31/305 reads (10%) | called by muse, mutect2, varscan2
- TPCN1 | c.1722G>A p.L574= | Silent (SNP) | VAF 17/167 reads (10%) | catalogued as rs776290635; called by muse, mutect2, varscan2
- TTC3 | c.1986C>T p.I662= | Silent (SNP) | VAF 38/204 reads (19%) | catalogued as rs754798772; called by muse, mutect2, varscan2
- TYRO3 | c.2376G>A p.Q792= | Silent (SNP) | VAF 56/258 reads (22%) | called by muse, mutect2, varscan2
- XPOT | c.1767C>T p.S589= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs766274967, COSV60346854; called by muse, mutect2, varscan2
- ZFHX2 | c.2110C>T p.L704= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- ZFHX3 | c.3672G>A p.Q1224= | Silent (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- ZFHX3 | c.705C>T p.D235= | Silent (SNP) | VAF 41/181 reads (23%) | catalogued as rs777145485; called by muse, mutect2, varscan2
- ZNF470 | c.579T>C p.F193= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- ZNF614 | c.519G>A p.T173= | Silent (SNP) | VAF 54/253 reads (21%) | catalogued as rs753164824; called by muse, mutect2, varscan2
- ZZEF1 | c.7290G>A p.E2430= | Silent (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-13821C>T | Intron (SNP) | VAF 34/162 reads (21%) | catalogued as rs998199277; called by muse, mutect2, varscan2
- AC134312.1 | n.1147G>T | RNA (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- AL021937.5 | chr22:32370900 del T | 3'Flank (DEL) | VAF 15/114 reads (13%) | called by mutect2, pindel, varscan2
- AL033381.1 | n.573T>C | RNA (SNP) | VAF 43/242 reads (18%) | called by muse, mutect2, varscan2
- AL035696.1 | n.186T>C | RNA (SNP) | VAF 32/189 reads (17%) | catalogued as rs969987199; called by mutect2, varscan2
- AL049777.1 | n.510+4504G>A | Intron (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- ATP6V1G3 | c.*30del | 3'UTR (DEL) | VAF 26/196 reads (13%) | catalogued as rs746211686; called by mutect2, varscan2
- CDHR1 | c.1783-18G>C | Intron (SNP) | VAF 32/361 reads (9%) | called by muse, mutect2
- CEP295 | c.5851-193del | Intron (DEL) | VAF 6/35 reads (17%) | catalogued as rs754124024; called by mutect2, pindel
- CLCN1 | c.774+193C>T | Intron (SNP) | VAF 46/275 reads (17%) | catalogued as rs780911735; called by muse, mutect2, varscan2
- CLCN7 | c.*356G>A | 3'UTR (SNP) | VAF 6/92 reads (7%) | catalogued as rs953985444, COSV51968923; called by muse, mutect2
- CLIC5 | c.1065+1550A>G | Intron (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- CPAMD8 | c.5567+79G>A | Intron (SNP) | VAF 30/120 reads (25%) | called by muse, mutect2, varscan2
- DENND10P1 | n.645C>T | RNA (SNP) | VAF 50/504 reads (10%) | catalogued as rs779507562; called by muse, mutect2
- DIS3L2 | c.2497-49G>A | Intron (SNP) | VAF 48/194 reads (25%) | catalogued as rs764280442; called by muse, mutect2, varscan2
- DNHD1 | c.9669+113del | Intron (DEL) | VAF 34/140 reads (24%) | called by mutect2, pindel, varscan2
- GALK2 | c.968-631C>T | Intron (SNP) | VAF 13/78 reads (17%) | catalogued as rs780422183; called by muse, varscan2
- HMCN1 | c.-5del | 5'UTR (DEL) | VAF 36/234 reads (15%) | catalogued as rs755887128; called by mutect2, varscan2
- ITGB2 | c.148-947del | Intron (DEL) | VAF 22/105 reads (21%) | catalogued as rs769752144; called by mutect2, varscan2
- KCNMA1 | c.378+820C>T | Intron (SNP) | VAF 16/196 reads (8%) | catalogued as rs760458966, COSV54271418; called by muse, mutect2
- KDM2B | c.126+761_126+763del | Intron (DEL) | VAF 22/140 reads (16%) | catalogued as rs1555317664; called by pindel, varscan2
- MGP | c.*31del | 3'UTR (DEL) | VAF 49/234 reads (21%) | catalogued as rs752884981; called by mutect2, pindel, varscan2
- OLFM1 | chr9:135087301 G>A | 5'Flank (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- PABPC5 | c.*1G>C | 3'UTR (SNP) | VAF 22/87 reads (25%) | called by mutect2, varscan2
- PMPCA | c.1408+65C>T | Intron (SNP) | VAF 35/114 reads (31%) | catalogued as rs540666048; called by muse, mutect2, varscan2
- RIIAD1 | c.-1125C>A | 5'UTR (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- RPS6KB2 | c.458-230G>T | Intron (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
- SLC9A5 | c.733+103C>T | Intron (SNP) | VAF 35/172 reads (20%) | catalogued as COSV100236991; called by muse, mutect2, varscan2
- SMURF1 | c.-35C>T | 5'UTR (SNP) | VAF 76/278 reads (27%) | called by muse, mutect2, varscan2
- TAF10 | c.*276G>A | 3'UTR (SNP) | VAF 32/288 reads (11%) | catalogued as rs367866686; called by muse, mutect2, varscan2
- TAF2 | c.*17C>A | 3'UTR (SNP) | VAF 38/236 reads (16%) | catalogued as rs756758058; called by muse, mutect2, varscan2
- TMEM167B | chr1:109100374 C>A | 3'Flank (SNP) | VAF 60/334 reads (18%) | called by muse, mutect2, varscan2
- UBR7 | c.*1942del | 3'UTR (DEL) | VAF 30/138 reads (22%) | called by mutect2, pindel, varscan2
- VCAN | c.1042+44del | Intron (DEL) | VAF 10/64 reads (16%) | catalogued as COSV99424942; called by mutect2, varscan2
- WASHC4 | c.2514+41G>A | Intron (SNP) | VAF 21/173 reads (12%) | catalogued as rs777313800; called by muse, mutect2, varscan2
- WDR3 | c.171+185A>G | Intron (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- ZNF688 | c.310+72C>A | Intron (SNP) | VAF 12/165 reads (7%) | called by muse, mutect2
- ZNF849P | n.1468C>A | RNA (SNP) | VAF 35/189 reads (19%) | called by mutect2, varscan2
